Somatic mutation profile of tumor specimen TCGA-43-8115-01A (aliquot TCGA-43-8115-01A-11D-2244-08) from TCGA case TCGA-43-8115, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.3 years (26,406 days).
Specimen TCGA-43-8115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9a2eb61-4fc9-4262-b652-47c357fe3953.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-8115-10A (Blood Derived Normal), aliquot TCGA-43-8115-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1410d7e5-c90e-495a-bf7d-122f99e488b2

The open-access MAF lists 226 somatic variants for this specimen: 166 protein-altering or splice-affecting, 51 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 51, Nonsense Mutation 5, Frame Shift Del 4, 3'UTR 3, Splice Site 3, RNA 3, Intron 2, Splice Region 2, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 43/175 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2094G>C p.R698S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131690891, COSV57297177, COSV99927128; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3541C>G p.Q1181E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.267); catalogued as COSV101330201; called by muse, mutect2, varscan2
- ABCG2 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV99420368; called by muse, mutect2, varscan2
- AC104389.6 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs281864490, COSV57963758; called by muse, mutect2, varscan2
- ACACB | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV100623354; called by muse, mutect2, varscan2
- ACD | c.1552G>C p.V518L (on ENST00000620338; = p.V429L on NM_022914.3) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99538029; called by muse, mutect2
- ACTR10 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99581403; called by muse, mutect2, varscan2
- ACTRT1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.803); catalogued as COSV100947785, COSV64419769; called by muse, mutect2, varscan2
- ADGRG4 | c.7451C>G p.A2484G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99797210; called by muse, mutect2, varscan2
- AFM | c.1224C>A p.S408R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs866253965, COSV99889329; called by muse, mutect2, varscan2
- AHNAK | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99949999; called by muse, varscan2
- AP4E1 | c.3406G>A p.G1136R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.178); catalogued as COSV99957289; called by muse, mutect2
- ARHGEF40 | c.3522G>T p.K1174N | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100070750; called by muse, mutect2, varscan2
- ASTN1 | c.1523+1G>T p.X508_splice | Splice Site (SNP) | VAF 255/871 reads (29%) | catalogued as COSV56066602, COSV99923348; called by muse, mutect2, varscan2
- ASTN2 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs201644531, COSV57755872; called by muse, mutect2, varscan2
- ATP13A2 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100454508; called by muse, mutect2, varscan2
- ATP13A3 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 68/606 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99757732; called by muse, mutect2, varscan2
- ATP6V0D2 | c.387C>A p.C129* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV99572113; called by muse, mutect2, varscan2
- ATRX | c.2075C>A p.S692* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100971576, COSV64870948; called by muse, mutect2, varscan2
- AUTS2 | c.3211A>G p.I1071V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV100719689; called by muse, varscan2
- BCCIP | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99502012; called by muse, mutect2, varscan2
- BCL6 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV99216116; called by muse, mutect2
- BRWD3 | c.3673A>C p.S1225R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100956624, COSV64751180; called by muse, mutect2, varscan2
- BTBD9 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100022966; called by muse, mutect2, varscan2
- BTNL8 | c.8T>A p.L3H | Missense Mutation (SNP) | VAF 50/455 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99180596; called by muse, mutect2, varscan2
- C15orf39 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100641507; called by muse, mutect2, varscan2
- C8B | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV100980940; called by muse, mutect2, varscan2
- CABP1 | c.836G>A p.G279D (on ENST00000316803 / NM_001033677.1; = p.G76D on NM_004276.5) | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99974942; called by muse, mutect2, varscan2
- CBLN2 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV99504696; called by muse, mutect2, varscan2
- CCDC73 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV58796325, COSV58806787; called by muse, mutect2, varscan2
- CCDC85B | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.539); catalogued as COSV100440993; called by muse, mutect2
- CD1A | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV99192636; called by muse, mutect2, varscan2
- CD274 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as COSV101056151; called by muse, mutect2, varscan2
- CDH12 | c.2073G>T p.R691S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV99063505; called by muse, mutect2, varscan2
- CDH13 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV51823582, COSV99231844; called by muse, mutect2, varscan2
- CGB1 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.94); catalogued as COSV100031795; called by muse, mutect2, varscan2
- CGB2 | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.991); catalogued as COSV100031794; called by muse, mutect2
- CHAT | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as rs1369543428, COSV60323605; called by muse, mutect2, varscan2
- CLCN5 | c.1419G>C p.M473I | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100260435; called by muse, mutect2, varscan2
- CLTB | c.552G>C p.K184N (on ENST00000310418 / NM_007097.5; = p.K166N on NM_001834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/408 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs1266056358, COSV99220977; called by muse, mutect2
- CMYA5 | c.6362A>G p.K2121R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV101484435; called by muse, mutect2, varscan2
- CNOT1 | c.4988A>G p.Q1663R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV99801472; called by muse, mutect2, varscan2
- COL24A1 | c.266A>T p.Y89F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV100994122; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2991G>C p.Q997H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52109342, COSV99267886; called by muse, mutect2
- CPN2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV60470923, COSV99068620; called by muse, mutect2
- CRABP2 | c.83T>G p.M28R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV100957585; called by muse, mutect2
- CSF2RA | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100817989; called by muse, mutect2
- CSMD3 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV104398877, COSV99839841; called by muse, mutect2, varscan2
- CTNNA3 | c.1687T>C p.Y563H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101051896; called by muse, varscan2
- DAPK2 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99977812; called by muse, mutect2, varscan2
- DCSTAMP | c.356A>T p.K119I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99886336, COSV99887072; called by muse, mutect2, varscan2
- DENND2A | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99327122; called by muse, mutect2, varscan2
- DIAPH2 | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.641); catalogued as COSV100235736; called by muse, mutect2
- DIS3L | c.826G>A p.D276N (on ENST00000319212 / NM_001143688.3; = p.D193N on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV100055672; called by muse, mutect2, varscan2
- DMXL1 | c.7871C>T p.A2624V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs775183708, COSV60704987; called by mutect2, varscan2
- DOCK9 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs750091458, COSV59637175; called by muse, mutect2, varscan2
- DSG1 | c.2378T>A p.V793D | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.148); catalogued as COSV57134713, COSV99936660; called by muse, mutect2, varscan2
- DSP | c.1905G>T p.V635= | Splice Region (SNP) | VAF 59/119 reads (50%) | catalogued as COSV101131850; called by muse, mutect2, varscan2
- DTNA | c.1766C>A p.T589K | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV52008314; called by muse, mutect2, varscan2
- DTWD2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100406857, COSV100407190; called by mutect2, varscan2
- EDA2R | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV99491047; called by muse, mutect2
- EEFSEC | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1559891555, COSV54624063; called by muse, mutect2, varscan2
- EP300 | c.4400A>T p.Y1467F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54328389, COSV99607142, COSV99610059; called by muse, mutect2, varscan2
- FAM47A | c.2213C>A p.A738D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100650110; called by muse, mutect2, varscan2
- FBXO43 | c.1562G>A p.S521N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1563753225, COSV101413941; called by muse, mutect2, varscan2
- FNBP4 | c.2864G>T p.R955L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99772048; called by muse, mutect2, varscan2
- FRS2 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100166430; called by muse, mutect2, varscan2
- GABRA3 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV64797261; called by muse, mutect2, varscan2
- GALNT17 | c.1415A>G p.N472S | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs199835659, COSV61176656; called by muse, mutect2, varscan2
- GPHN | c.1043G>A p.R348Q (on ENST00000315266 / NM_001377519.1; = p.R381Q on NM_020806.5) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs200511259, COSV100017994; called by muse, mutect2, varscan2
- GPKOW | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782117251, COSV99332828; called by muse, mutect2, varscan2
- GPR82 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100220704; called by muse, mutect2, varscan2
- H2BW1 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV99475178; called by muse, mutect2, varscan2
- HEPACAM2 | c.515T>A p.V172E (on ENST00000394468 / NM_001039372.4; = p.V160E on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100506843, COSV59059203; called by muse, mutect2, varscan2
- HHIPL1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755813422, COSV58090278; called by muse, mutect2, varscan2
- IFIH1 | c.2650A>C p.K884Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99718950; called by muse, mutect2, varscan2
- INHBA | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54223942, COSV99638519; called by muse, mutect2, varscan2
- INTS2 | c.1477A>G p.S493G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99248974; called by muse, mutect2
- INTS6 | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100247294; called by muse, mutect2, varscan2
- ITPRID1 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV60076823; called by muse, mutect2, varscan2
- JKAMP | c.376G>T p.V126F (on ENST00000554271 / NM_001284201.1; = p.V112F on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.499); catalogued as COSV99711789; called by muse, mutect2, varscan2
- KCNQ2 | c.1763+1G>A p.X588_splice (on ENST00000359125 / NM_172107.4; = p.X560_splice on NM_004518.6) | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV60540187; called by muse, mutect2, varscan2
- KHSRP | c.1148C>G p.A383G | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV101231258; called by muse, mutect2, varscan2
- KIAA1210 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as COSV101274442; called by muse, mutect2, varscan2
- KIR2DL1 | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs2736416, COSV99383584, COSV99383745; called by muse, mutect2, varscan2
- KMT2C | c.1679A>T p.Q560L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs755653261, COSV100077564; called by muse, mutect2, varscan2
- LPIN2 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99859080; called by muse, mutect2, varscan2
- LRRC52 | c.336C>G p.N112K | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.349); catalogued as COSV99674166; called by muse, mutect2, varscan2
- LRRC7 | c.3262C>A p.P1088T (on ENST00000651989 / NM_001370785.2; = p.P1055T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV99230314; called by muse, mutect2, varscan2
- MAGEC1 | c.2986del p.Q996Rfs*5 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | catalogued as COSV99596607; called by mutect2, pindel, varscan2
- MAMLD1 | c.13A>C p.K5Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99476665; called by muse, mutect2, varscan2
- MAST1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263818; called by muse, mutect2, varscan2
- MCF2 | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1469770026, COSV100645235; called by muse, mutect2, varscan2
- MGA | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99581905; called by muse, mutect2, varscan2
- MGAM | c.2705T>A p.I902N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV72075229; called by muse, mutect2, varscan2
- MIA2 | c.1246A>G p.K416E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs775661674, COSV99698321; called by muse, mutect2, varscan2
- MS4A14 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV100280766; called by muse, mutect2, varscan2
- MTMR10 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747096897, COSV100076389; called by muse, mutect2, varscan2
- MTR | c.59A>T p.D20V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100856357; called by muse, varscan2
- MUC5AC | c.14278G>T p.V4760L | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as rs374724880, COSV100611634; called by muse, mutect2, varscan2
- NALCN | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99218251; called by muse, mutect2
- NCAN | c.1231A>G p.S411G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV99388501; called by muse, mutect2, varscan2
- NETO1 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.781); catalogued as COSV100199875; called by muse, mutect2, varscan2
- NLRP11 | c.1793T>G p.V598G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100789825; called by muse, mutect2
- NR0B1 | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV66764774; called by muse, mutect2, varscan2
- NRXN3 | c.1982G>T p.G661V (on ENST00000335750 / NM_001330195.2; = p.G288V on NM_004796.6) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100209972, COSV59712038, COSV59743788; called by muse, mutect2, varscan2
- NXPE3 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99840245; called by muse, mutect2, varscan2
- NXPE4 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100970580, COSV100970593; called by muse, mutect2
- NYX | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV100699500; called by muse, varscan2
- OBSCN | c.14509G>T p.A4837S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.118); catalogued as rs779686024, COSV99485290; called by muse, mutect2, varscan2
- OR10K2 | c.157A>T p.R53W | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV100149692; called by muse, mutect2, varscan2
- OR7C2 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as COSV99934666; called by muse, mutect2, varscan2
- OR8G1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); catalogued as COSV58381199; called by muse, mutect2, varscan2
- OR8K1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV54404248, COSV99687584; called by muse, mutect2
- OSBPL2 | c.173A>G p.Q58R (on ENST00000313733 / NM_144498.4; = p.Q46R on NM_014835.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100569370; called by muse, mutect2, varscan2
- PCDHB13 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782112774, COSV99507954; called by muse, mutect2
- PCSK5 | c.4784G>T p.R1595L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.414); catalogued as COSV101377740, COSV70448074; called by muse, mutect2, varscan2
- PDE6C | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101008866; called by muse, mutect2, varscan2
- PHF20 | c.2426A>G p.Y809C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); catalogued as rs770744773, COSV100926766; called by muse, mutect2, varscan2
- PHF20L1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99622280; called by muse, mutect2, varscan2
- PLD3 | c.1185+1G>A p.X395_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99397125; called by muse, varscan2
- PNMA5 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100721729, COSV62626408; called by muse, mutect2, varscan2
- POM121L12 | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV101374987, COSV101375000; called by muse, mutect2, varscan2
- PPFIA4 | c.2614C>T p.R872W (on ENST00000447715; = p.R873W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376273813; called by muse, mutect2, varscan2
- PPP1R13L | c.2074C>T p.H692Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100714901; called by muse, mutect2, varscan2
- PRDX2 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100040396; called by muse, mutect2, varscan2
- PRPF3 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1386410237, COSV100255165; called by muse, mutect2, varscan2
- QDPR | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845985; called by muse, mutect2, varscan2
- RASSF9 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 27/165 reads (16%) | catalogued as COSV100771627; called by muse, mutect2, varscan2
- REM2 | c.519G>A p.Q173= | Splice Region (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99944791; called by muse, mutect2, varscan2
- REV1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99301593; called by muse, mutect2, varscan2
- RIMS2 | c.1652A>G p.H551R (on ENST00000666250 / NM_001348490.2; = p.H359R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as COSV99204721; called by muse, mutect2, varscan2
- SCEL | c.1105G>C p.D369H (on ENST00000349847 / NM_144777.3; = p.D349H on NM_003843.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs372992849, COSV62993169; called by muse, mutect2
- SH3RF2 | c.1679C>G p.P560R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV100768085; called by muse, mutect2, varscan2
- SHMT1 | c.229T>G p.Y77D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100363702; called by muse, mutect2
- SIGLEC6 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100585762; called by muse, mutect2, varscan2
- SLC18A1 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368999; called by muse, mutect2, varscan2
- SLC1A4 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99309258; called by muse, mutect2
- SLC9A6 | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857959; called by muse, mutect2, varscan2
- SLFN12 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs943145903, COSV100513256; called by muse, mutect2, varscan2
- ST14 | c.2115C>G p.D705E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99599203; called by muse, mutect2, varscan2
- ST8SIA5 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | PolyPhen probably damaging (0.998); catalogued as rs933463771, COSV100164554; called by muse, mutect2, varscan2
- TMEM132D | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV70623558; called by muse, mutect2, varscan2
- UBQLN3 | c.77T>A p.V26E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100294002; called by muse, mutect2, varscan2
- USP17L2 | c.267C>A p.C89* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100414788; called by muse, mutect2, varscan2
- VN1R1 | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100320783; called by muse, mutect2, varscan2
- YWHAG | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs1426519806, COSV100297473; called by muse, mutect2, varscan2
- ZAN | c.4666G>T p.A1556S | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1238516103, COSV100770529; called by muse, mutect2
- ZGPAT | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1176701629, COSV58874264; called by muse, mutect2, varscan2
- ZMYM4 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100111240; called by muse, mutect2
- ZNF230 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.873); catalogued as COSV101432171; called by muse, mutect2, varscan2
- ZNF408 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100305714; called by muse, mutect2, varscan2
- ZNF519 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV101645599, COSV73913569; called by muse, mutect2, varscan2
- ZNF551 | c.1484G>C p.R495T | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV99990403; called by muse, mutect2
- ZNF827 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs771386798, COSV101061861; called by muse, mutect2, varscan2
- C5orf34 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- DMBT1 | c.7590_7605del p.Q2530Hfs*24 (on ENST00000338354 / NM_001377530.1; = p.Q1773Hfs*24 on NM_004406.3) | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- FLNA | c.7184G>A p.R2395Q (on ENST00000369850 / NM_001110556.2; = p.R2387Q on NM_001456.3) | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- IGHM | c.554_577del p.K185_Q192del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- IGKV1D-16 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MRC1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PPP4R1 | c.397dup p.L133Pfs*6 (on ENST00000400556 / NM_001042388.3; = p.L116Pfs*6 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- STK36 | c.3675_3700del p.E1226Pfs*43 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel
- TMOD3 | c.242_243del p.K81Rfs*35 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- ABCC12 | c.3805C>A p.R1269= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV100253329; called by muse, mutect2
- ADAMTS2 | c.2916C>T p.R972= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs201390812, COSV99284141; called by muse, mutect2, varscan2
- AIFM1 | c.135T>A p.P45= | Silent (SNP) | VAF 46/340 reads (14%) | catalogued as COSV99781498; called by muse, mutect2, varscan2
- ANAPC5 | c.1377G>A p.Q459= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- ANKRD30A | c.3498G>A p.G1166= (on ENST00000611781; = p.G1110= on NM_052997.2) | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs879120235, COSV64603604; called by muse, mutect2, varscan2
- APLF | c.387A>G p.P129= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV100377100; called by muse, mutect2, varscan2
- ARMCX2 | c.312C>T p.S104= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs1556066863, COSV57529451; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1260G>T p.P420= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- ATRNL1 | c.1248A>T p.A416= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as COSV100747098; called by muse, mutect2, varscan2
- BCAP31 | c.438G>T p.A146= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100799021; called by muse, mutect2, varscan2
- CIT | c.6078A>T p.S2026= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99951226; called by muse, mutect2, varscan2
- CTPS1 | c.519G>A p.E173= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV101009440, COSV65451725; called by muse, mutect2, varscan2
- CYTH4 | c.27G>T p.A9= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV50636798, COSV99958240; called by muse, mutect2, varscan2
- DPP4 | c.1770C>A p.I590= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV100859143, COSV62109737; called by muse, mutect2
- HEPH | c.708C>T p.N236= (on ENST00000343002; = p.N290= on NM_138737.5) | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100295899; called by muse, mutect2, varscan2
- HERC1 | c.1089T>C p.G363= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101497039; called by muse, mutect2, varscan2
- HGF | c.1080T>G p.S360= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV99738787; called by muse, mutect2, varscan2
- HNF1A | c.774C>A p.L258= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99983093; called by muse, mutect2, varscan2
- HRNR | c.747T>C p.S249= | Silent (SNP) | VAF 127/437 reads (29%) | catalogued as COSV64260321; called by muse, mutect2, varscan2
- KIAA1549 | c.2805A>G p.T935= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs749333094, COSV99652279; called by muse, mutect2, varscan2
- KIT | c.1218T>C p.N406= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1286559821, COSV99855528; called by muse, mutect2, varscan2
- KNG1 | c.963C>T p.F321= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs778612274, COSV53977726; called by muse, mutect2, varscan2
- MAGEA1 | c.495C>T p.T165= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV63118463; called by muse, mutect2, varscan2
- MAP3K15 | c.3384C>A p.V1128= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as COSV100135938; called by muse, mutect2, varscan2
- MBD5 | c.1999T>C p.L667= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs529715710, COSV101290288; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEF2C | c.171T>C p.Y57= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs747171130, COSV100426334; called by muse, mutect2, varscan2
- NAALADL2 | c.2280G>A p.E760= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV101495518; called by muse, mutect2
- PAX1 | c.891C>A p.G297= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV68271274; called by muse, mutect2, varscan2
- PHC1 | c.546G>A p.A182= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs752134578, COSV101418717; called by muse, mutect2, varscan2
- PKNOX2 | c.843G>T p.L281= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100021804, COSV53543915; called by muse, mutect2, varscan2
- PPP1R1A | c.441C>T p.G147= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV99226556; called by muse, mutect2, varscan2
- PRB2 | c.1131T>A p.P377= | Silent (SNP) | VAF 14/240 reads (6%) | catalogued as COSV101231510; called by muse, mutect2
- RGS6 | c.741T>C p.H247= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100667134; called by muse, mutect2, varscan2
- RPS6KA5 | c.1846T>C p.L616= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100003354; called by muse, mutect2, varscan2
- SERPINB11 | c.978A>T p.L326= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- SFSWAP | c.1584T>G p.S528= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV99906474; called by muse, mutect2, varscan2
- SHANK2 | c.3819G>A p.L1273= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99576567; called by muse, mutect2, varscan2
- SHANK2 | c.2328C>A p.V776= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99576569; called by muse, mutect2, varscan2
- SIAE | c.21A>T p.V7= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99704222; called by muse, mutect2, varscan2
- SIGLEC9 | c.1050C>T p.V350= | Silent (SNP) | VAF 20/381 reads (5%) | catalogued as rs554428812, COSV99143552; called by muse, mutect2
- SLC17A6 | c.1158G>A p.K386= | Silent (SNP) | VAF 56/230 reads (24%) | catalogued as rs771276225, COSV99582527; called by muse, mutect2, varscan2
- SNRNP40 | c.1065G>A p.E355= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99745784; called by muse, mutect2, varscan2
- STIL | c.2595C>T p.N865= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99681409; called by muse, varscan2
- TARS3 | c.2373G>A p.R791= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100255087; called by muse, mutect2, varscan2
- TAS2R41 | c.366G>T p.L122= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV101281517; called by muse, mutect2, varscan2
- TLL1 | c.1560G>C p.L520= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV99289437; called by muse, mutect2, varscan2
- TTN | c.62253A>G p.Q20751= (on ENST00000591111; = p.Q13327= on NM_003319.4) | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as rs1188399619, COSV100633717; called by muse, mutect2, varscan2
- TYW3 | c.288C>A p.A96= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100904915; called by muse, mutect2, varscan2
- ZFHX4 | c.1812A>T p.G604= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99268647; called by muse, mutect2, varscan2
- ZNF182 | c.132G>T p.L44= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV100527263; called by muse, mutect2, varscan2
- ZNF875 | c.1332A>T p.T444= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100183597; called by muse, mutect2, varscan2
- COL11A1 | c.898-291T>A | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs769994618; called by muse, mutect2, varscan2
- F5 | c.*1A>G | 3'UTR (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100889274; called by muse, mutect2, varscan2
- IGKV1-13 | n.194G>T | RNA (SNP) | VAF 15/69 reads (22%) | called by muse, varscan2
- KLK3 | c.631-401G>T | Intron (SNP) | VAF 16/194 reads (8%) | catalogued as COSV100386140; called by muse, mutect2
- LEKR1 | c.*877G>C | 3'UTR (SNP) | VAF 15/102 reads (15%) | catalogued as COSV100739394; called by muse, mutect2
- MIR1302-7 | n.6A>G | RNA (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302030 T>A | 5'Flank (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- SORCS1 | c.*161C>G | 3'UTR (SNP) | VAF 6/37 reads (16%) | catalogued as rs1478404790, COSV53870332, COSV99550980; called by muse, mutect2, varscan2
- WASF4P | n.1284C>A | RNA (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
